CCDI case PBBKKX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/40d4b8b4-1d0b-4ef8-b079-cf56c2af4fa8

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 6.7 years (2,456 days).

Biospecimens (3 samples)
- Sample 0DCUKR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCUKY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCUL3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
